Surgical pathology report (de-identified scan), TCGA case TCGA-XF-AAMH, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of Southern California, specimen TCGA-XF-AAMH-01A (Primary Tumor).

[page 1 of 5]
SURGICAL PATHOLOGY REPORT

Patient
Patient
DOB/Age
Client:

Received:

SPECIMEN:

A: "Right distal ureter F/S"
B: "Left distal ureter F/S"
C: "Right common iliac lymph nodes"
D: "Urethral margin F/S"
E: "Urinary bladder & prostate"
F: "Aortic bifurcation lymph nodes"
G: "Right node of cloquet"
H: "Right obturator / hypogastric lymph nodes"
I: "Left obturator / hypogastric lymph nodes"
J: "Left proximal ureter"
K: "Right proximal ureter"

ICD O-3
Carcinoma, urothelial NOS
8124/3
Site 4 Bladder NOS
C67.9
Jt 3/26/14

CLINICAL DIAGNOSIS AND HISTORY:
{Not Provided}

PRE-OPERATIVE DIAGNOSIS:
Bladder cancer

POST-OPERATIVE DIAGNOSIS:
Same

INTRAOPERATIVE CONSULTATION:

FROZEN SECTION DIAGNOSIS:
AFS: Right distal ureter:
- benign urothelium

BFS: Left distal ureter:
- hydroureter with chronic inflammation and atypical hyperplasia

CFS: Right common iliac lymph nodes:
- no tumor seen

DFS: Urethral margin:

[page 2 of 5]
- no tumor seen

GROSS DESCRIPTION:

A: The specimen is received fresh from the O.R. and labelled "Right distal ureter F/S." It consists of a segment of ureter measuring 0.2 x 0.4 cm. The specimen is entirely submitted for frozen section in cassette AFS.

B: The specimen is received fresh from the O.R. and labelled "Left distal ureter F/S." It consists of a segment of ureter measuring 0.3 x 0.5 cm. The specimen is entirely submitted for frozen section in cassette BFS.

C: The specimen is received fresh from the O.R. and labelled "Right common iliac lymph nodes." It consists of two nodes, one measuring 3.5 x 2 x 0.8 cm, and the other measuring 1.5 x 0.7 x 0.5 cm. The entire specimen is embedded for frozen section in cassette CFS.

D: The specimen is received fresh from the O.R. and labelled "Urethral margin F/S." It consists of a fragment of pink-tan tissue measuring 2.2 x 0.9 x 0.4 cm. The entire specimen is submitted for frozen section in cassette DFS.

E: The specimen is received fresh from the O.R. and labelled "Urinary bladder & prostate." It consists of a cystoprostatectomy specimen with overall measurements of 14 x 10.5 x 4.5 cm. The peritoneum measures 25 x 10.7 cm and is pink-tan to gray and unremarkable. The right distal ureter measures 6.4 cm in length and is 0.7 cm in circumference, and the left distal ureter measures 3.0 cm in length and 1.7 cm in circumference and appears slightly ragged and erythematous. The bladder measures 8 x 6 cm and measures 1.7 cm in thickness. In the left posterior wall of the bladder is a pink-tan, fungating tumor measuring 4.5 x 3.4 cm. The tumor grossly appears to measure 2.6 cm in thickness and appears to invade into the surrounding perivesical fatty tissue. The tumor abuts the ureterovesical junction but does not appear to invade into the left ureter. The remaining bladder mucosa is pink-tan and slightly erythematous. The prostate measures 4 x 3 x 2.7 cm with an enlarged median bar measuring 1.5 x 1.5 x 0.5 cm. The prostatic urethra measures 2.2 cm in length and 1.3 cm in circumference and the verumontanum measures 0.5 x 0.4 x 0.4 cm. The left seminal vesicle measures 4.7 x 2.2 cm, and the right seminal vesicle measures 4.5 x 1.6 cm. Serial sections of the prostate show pale tan parenchyma with a hypertrophic nodule in the left lobe, measuring 2.5 cm in greatest dimension. Representative sections are submitted in 15 cassettes.

F: The specimen is received in formalin and labelled "Aortic bifurcation lymph nodes." It consists of a fragment of yellow fatty tissue measuring 3.5 x 2 x 0.5 cm. The entire specimen is submitted in one cassette.

G: The specimen is received in formalin and labelled "Right node of cloquet." It consists of a rubbery to firm, pink-tan lymph node measuring 1.4 x 0.9 x 0.7 cm. Bivalving the lymph node reveals a pink-tan, smooth, homogeneous cut surface. The entire specimen is submitted in one cassette.

H: The specimen is received in formalin and labelled "Right obturator / hypogastric lymph nodes." It consists of multiple fragments of yellow adipose tissue measuring in aggregate 8.4 x 7.5 x 1.7 cm. Multiple lymph nodes are palpated, the largest measuring 2.4 cm in greatest dimension and containing a

[page 3 of 5]
pink-tan, smooth, homogeneous cut surface. Representative sections are submitted in six cassettes.

I: The specimen is received in formalin and labelled "Left obturator / hypogastric lymph nodes." It consists of multiple fragments of yellow adipose tissue measuring in aggregate 8 x 6.5 x 1.7 cm. Multiple lymph nodes are palpated, the largest measuring 2.3 cm in greatest dimension and containing a pink-tan, smooth, homogeneous cut surface. Representative sections are submitted in eight cassettes.

J: The specimen is received in formalin and labelled "Left proximal ureter." It consists of a segment of ureter measuring 1 x 1 cm. The entire specimen is submitted in one cassette.

K: The specimen is received in formalin and labelled "Right proximal ureter." It consists of a segment of ureter measuring 1.2 cm in length and 0.6 cm in diameter. The entire specimen is submitted in one cassette.

SECTIONS:

AFS: frozen section, right distal ureter all embedded
BFS: frozen section, left distal ureter all embedded
CFS: frozen section, right common iliac lymph nodes all embedded
DFS: frozen section, urethral margin all embedded
E1: left ureterovesical junction
E2: right ureterovesical junction
E3,4: tumor
E5,6: tumor at the perivesical fat
E7: tumor adjacent to normal-appearing mucosa
E8: non-tumorous mucosa
E9: hypertrophic prostatic median bar
E10: left lobe of prostate with hypertrophic nodule
E11: right lobe of prostate
E12: left seminal vesicle and vas deferens
E13: right seminal vesicle and vas deferens
E14: peritoneum
E15: erythematous area in left ureter
F: aortic bifurcation lymph nodes, all embedded
G: right node of Cloquet all embedded
H1,2: right obturator/hypogastric lymph nodes; largest lymph node-bisected
H3: one lymph node, bisected
H4: three lymph nodes, each bisected
H5: one lymph node, bisected
H6: one lymph node, bisected
I1,2: left obturator/hypogastric lymph nodes; largest lymph node, bisected
I3,4: another large lymph node, bisected
I5: two lymph nodes, each bisected
I6: two lymph nodes, each bisected
I7,8: lymph nodes
J: left proximal ureter all embedded
K: right proximal ureter all embedded

[page 4 of 5]
MICROSCOPIC EXAMINATION:

A-K: See final microscopic-diagnoses.

FINAL DIAGNOSIS:

RIGHT DISTAL URETER (A):

FROZEN SECTION DIAGNOSIS:

- BENIGN UROTHELIUM

FINAL DIAGNOSIS:

- BENIGN UROTHELIUM

LEFT DISTAL URETER (B):

FROZEN SECTION DIAGNOSIS:

- HYDROURETER WITH CHRONIC INFLAMMATION AND ATYPICAL HYPERPLASIA

FINAL DIAGNOSIS:

- HYDROURETER WITH CHRONIC INFLAMMATION AND ATYPICAL HYPERPLASIA

RIGHT COMMON ILIAC LYMPH NODES (C):

FROZEN SECTION DIAGNOSIS:

- NO TUMOR SEEN

FINAL DIAGNOSIS:

- NO TUMOR SEEN IN ONE LYMPH NODE IDENTIFIED (0/1)

URETHRAL MARGIN (D):

FROZEN SECTION DIAGNOSIS:

- NO TUMOR SEEN

FINAL DIAGNOSIS:

- NO TUMOR SEEN

*Per TSS, 5% squamous
10% glandular*

URINARY BLADDER AND PROSTATE, CYSTOPROSTATECTOMY (E):

- HIGH GRADE UROTHELIAL CARCINOMA, GRADE 3/4, WITH SQUAMOUS AND GLANDULAR DIFFERENTIATION, GROSSLY AND MICROSCOPICALLY INVADING THROUGH THE BLADDER WALL
- EXTENSIVE LYMPHOVASCULAR INVASION
- VASCULAR INVASION INVOLVING SUBPERIURETHRAL (PROSTATIC), PERIURETERAL, AND ADJACENT TO SEMINAL VESICLE
- INVASION OF SEMINAL VESICLE WALL BY HIGH GRADE UROTHELIAL CARCINOMA
- BENIGN STROMAL AND GLANDULAR PROSTATIC HYPERPLASIA

AORTIC BIFURCATION LYMPH NODES (F):

- NO LYMPH NODES IDENTIFIED (0/0)

RIGHT NODE OF CLOQUET (G):

- NO TUMOR SEEN IN ONE LYMPH NODE IDENTIFIED (0/1)

RIGHT OBTURATOR/HYPOGASTRIC LYMPH NODES (H):

- NO TUMOR SEEN IN 14 LYMPH NODES IDENTIFIED (0/14)

[page 5 of 5]
LEFT OBTURATOR/HYPOGASTRIC LYMPH NODES (I):

- METASTATIC HIGH GRADE UROTHELIAL CARCINOMA TO 4 OF 28 LYMPH NODES IDENTIFIED (4/28)
- MULTIFOCAL LYMPHOVASCULAR INVASION OF HIGH GRADE UROTHELIAL CARCINOMA IN PERINODAL SOFT TISSUE

LEFT PROXIMAL URETER (J):

- NO TUMOR SEEN
- BENIGN UROTHELIAL MUCOSA

RIGHT PROXIMAL URETER (K):

- NO TUMOR SEEN
- BENIGN UROTHELIAL MUCOSA

COMMENT

Sections confirm the gross impression that this tumor is through the wall and into perivesical fat . This is an interesting tumor in that there is rather extensive vascular space invasion in sections from the left side of the specimen as well as the prostatic urethra.

Staff Pathologist:

Resident/Fellow:

By his/her/their electronic signature(s), the senior pathologist(s) certifies that he/she/they personally conducted a gross and/or microscopic examination(s) of the described specimen(s) and made the diagnosis with his/her/their electronic signature(s).

Final Diagnosis Text End for :

FEE CODES: A: 88305

B: 88305

C: 88305

D: 88305

E: 88309

F: 88305

G: 88305

H: 88307

I: 88307

J: 88305

K: 88305 ICD-9-CM CODES:

page 5

Source: NCI Genomic Data Commons file 50c37af9-d16c-49b3-9978-c20de317fec9 (TCGA-XF-AAMH.5262C4FA-045C-4F50-8C82-D5CA53A406F1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).